Somatic mutation profile of tumor specimen TARGET-30-PAMMWD-01A (aliquot TARGET-30-PAMMWD-01A-01W) from TARGET case TARGET-30-PAMMWD, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.2 years (812 days).
Specimen TARGET-30-PAMMWD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b341a7e0-89e1-4e2c-b043-a97f2b977a67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAMMWD-10A (Blood Derived Normal), aliquot TARGET-30-PAMMWD-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/880bedfd-15fe-479d-869e-79c6a0ce695a

The open-access MAF lists 121 somatic variants for this specimen: 94 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 26, Nonsense Mutation 8, Splice Site 3, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.2420G>A p.G807E (on ENST00000272895 / NM_173076.3; = p.G489E on NM_015657.3) | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55962946; called by muse, mutect2
- ALDH16A1 | c.408C>A p.D136E | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV53194681; called by muse, mutect2, varscan2
- ARID1B | c.4475G>T p.R1492M | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.31); catalogued as COSV99269070; called by muse, mutect2
- AVL9 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV59466541; called by muse, mutect2, varscan2
- CAPZB | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51648366; called by muse, mutect2, varscan2
- CDH23 | c.6517G>A p.E2173K | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.887); catalogued as rs770659035, COSV56470850; called by muse, mutect2, varscan2
- CTNND2 | c.2315C>A p.S772* | Nonsense Mutation (SNP) | VAF 16/244 reads (7%) | catalogued as COSV58867189; called by muse, mutect2
- DDX39A | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV54392087, COSV99660559; called by muse, mutect2, varscan2
- FAM168A | c.181A>G p.T61A (on ENST00000064778 / NM_001286050.2; = p.T52A on NM_015159.3) | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.186); catalogued as rs751717764, COSV50358367; called by muse, mutect2, varscan2
- FBXO34 | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58254997; called by muse, mutect2, varscan2
- FOXO4 | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV58574913; called by muse, mutect2
- FRMD5 | c.1639C>A p.Q547K | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV101296400, COSV68720556; called by muse, mutect2
- GRM1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 24/891 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51154535; called by muse, mutect2
- GSDMB | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 179/1192 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58345919; called by muse, mutect2, varscan2
- JCAD | c.2215G>A p.G739S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1305401906; called by muse, mutect2
- KLHDC7B | c.1403C>T p.P468L (on ENST00000395676; = p.P1109L on NM_138433.5) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV67464826; called by muse, mutect2, varscan2
- KLK9 | c.673T>A p.C225S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368879303, COSV51590497; called by muse, mutect2
- LIMCH1 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100573795; called by muse, mutect2
- LIN37 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.268); catalogued as rs796989672, COSV50000778; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.89G>C p.W30S | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53280148; called by muse, mutect2, varscan2
- LINS1 | c.965C>A p.A322D | Missense Mutation (SNP) | VAF 32/1138 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as COSV59078313; called by muse, mutect2
- LUZP1 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1168834878, COSV56500836; called by muse, mutect2
- MDN1 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 168/349 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV65523337; called by muse, mutect2, varscan2
- MED12L | c.2480C>A p.A827D | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV56401295; called by muse, mutect2
- MFSD2B | c.914T>C p.V305A | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.124); catalogued as rs747286855; called by muse, mutect2
- NCKAP5 | c.5456C>A p.S1819Y | Missense Mutation (SNP) | VAF 29/861 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.106); catalogued as COSV58437073; called by muse, mutect2
- NFIA | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as COSV63607807; called by muse, mutect2, varscan2
- NKX2-5 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV61299326; called by mutect2, varscan2
- ORAI3 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV52688981; called by muse, mutect2, varscan2
- PHTF1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs1356057230; called by muse, mutect2
- POLR1G | c.1160C>T p.T387M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs763442500, COSV50004436; called by muse, varscan2
- PPP4R1 | c.2039G>T p.R680L (on ENST00000400556 / NM_001042388.3; = p.R663L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/226 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53282214; called by muse, mutect2
- PRDM2 | c.4639C>A p.P1547T | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs144820187, COSV52443382; called by muse, mutect2, varscan2
- PRKAB2 | c.538+1G>A p.X180_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as COSV54213530; called by muse, mutect2, varscan2
- PTGER4 | c.1417C>A p.Q473K | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs767926548, COSV56721249; called by muse, mutect2, varscan2
- RNF103 | c.142C>A p.L48M | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52895689; called by muse, mutect2, varscan2
- RPAP1 | c.2455G>A p.D819N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV58540080; called by muse, mutect2
- SERTAD4 | c.594C>G p.H198Q | Missense Mutation (SNP) | VAF 128/1009 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as COSV65399551; called by muse, mutect2, varscan2
- SLC10A4 | c.896C>A p.A299D | Missense Mutation (SNP) | VAF 85/652 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as COSV56719019; called by muse, mutect2, varscan2
- SLC16A1 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs763573918, COSV63708894; called by muse, mutect2
- SLC32A1 | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54146082; called by muse, mutect2, varscan2
- SLC44A4 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV57669687; called by muse, mutect2
- SPESP1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 99/222 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.3); catalogued as COSV52990516; called by muse, mutect2, varscan2
- TCP11L1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs748595723, COSV100178300, COSV57515754; called by muse, mutect2
- TMEM132E | c.1279G>T p.V427F (on ENST00000321639; = p.V517F on NM_001304438.2) | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV58698026; called by muse, mutect2, varscan2
- TMPRSS7 | c.2369C>A p.S790* (on ENST00000452346; = p.S664* on NM_001042575.2) | Nonsense Mutation (SNP) | VAF 36/498 reads (7%) | catalogued as COSV69981675; called by muse, mutect2
- TP63 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as COSV53209215; called by muse, mutect2, varscan2
- TRPM8 | c.2447+1G>A p.X816_splice | Splice Site (SNP) | VAF 10/118 reads (8%) | catalogued as rs1260060225; called by muse, mutect2
- TTN | c.51271G>A p.V17091I (on ENST00000591111; = p.V9667I on NM_003319.4) | Missense Mutation (SNP) | VAF 67/450 reads (15%) | PolyPhen benign (0.006); catalogued as COSV60132905; called by muse, mutect2, varscan2
- VAV3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.316); catalogued as rs1466441587; called by muse, mutect2
- VPS4B | c.179C>A p.A60E | Missense Mutation (SNP) | VAF 13/261 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1233871143; called by muse, mutect2
- ADAM33 | c.2028_2029insTT p.P677Ffs*141 | Frame Shift Ins (INS) | VAF 3/29 reads (10%) | called by mutect2, varscan2
- ADAMTS1 | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ADAMTS14 | c.870+4_870+7del p.X290_splice | Splice Site (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- AGO1 | c.2035C>A p.H679N | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- AP2B1 | c.1660C>A p.L554I | Missense Mutation (SNP) | VAF 120/1930 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- CCKAR | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2
- CCR3 | c.1020C>A p.S340R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CLCA4 | c.815C>T p.T272I | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2
- DDX4 | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DSP | c.4318G>A p.V1440M | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- E2F7 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FBXO11 | c.692C>A p.P231H (on ENST00000403359 / NM_001190274.2; = p.P147H on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- FDFT1 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2
- GOLGA2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- HEATR1 | c.2262C>A p.H754Q | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.043); called by muse, mutect2
- HPD | c.1072G>T p.G358C | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ITGA6 | c.3140C>A p.A1047D (on ENST00000442250; = p.A1008D on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- KCNK2 | c.325G>C p.V109L (on ENST00000444842 / NM_001017425.3; = p.V94L on NM_014217.4) | Missense Mutation (SNP) | VAF 53/755 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.463); called by muse, mutect2
- KLHL28 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 12/247 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- KRT33A | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- KRT4 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- LARP4 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LGSN | c.1170C>A p.S390R | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- MACF1 | c.14281G>T p.E4761* (on ENST00000372915; = p.E2694* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- NIPSNAP2 | c.636C>A p.F212L | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, mutect2
- NUP58 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- OXSM | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PDE4D | c.1929C>A p.F643L (on ENST00000340635 / NM_001104631.2; = p.F507L on NM_006203.4) | Missense Mutation (SNP) | VAF 13/264 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- PHAX | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- PHF21A | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PLB1 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- SETX | c.5443C>A p.P1815T | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.457); called by muse, mutect2
- SLC12A8 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 72/834 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- SLC15A2 | c.685G>A p.V229I | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2
- SLC25A19 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SLC7A8 | c.299T>C p.I100T | Missense Mutation (SNP) | VAF 10/332 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- STARD3 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- TGFBR1 | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 61/965 reads (6%) | called by muse, mutect2
- TMPRSS2 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- TSC22D1 | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.048); called by muse, mutect2
- ULK4 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/229 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- WHRN | c.810C>A p.H270Q | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF445 | c.2187G>T p.K729N | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, mutect2
- C1orf116 | c.456G>A p.Q152= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- CCR8 | c.432G>T p.V144= | Silent (SNP) | VAF 56/1154 reads (5%) | catalogued as COSV58338008; called by muse, mutect2
- CDK5RAP2 | c.5079C>T p.D1693= | Silent (SNP) | VAF 21/187 reads (11%) | catalogued as rs965761601, COSV62575236; called by muse, mutect2, varscan2
- DQX1 | c.426G>T p.L142= | Silent (SNP) | VAF 15/416 reads (4%) | called by muse, mutect2
- DUSP16 | c.792C>T p.D264= | Silent (SNP) | VAF 14/472 reads (3%) | catalogued as rs759125027; called by muse, mutect2
- FAM214B | c.876G>T p.G292= | Silent (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- FLT4 | c.3864G>A p.E1288= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs772310898, COSV56112021; called by muse, mutect2, varscan2
- FSCN3 | c.1431C>A p.A477= | Silent (SNP) | VAF 12/402 reads (3%) | called by muse, mutect2
- GPNMB | c.183G>A p.V61= | Silent (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- IKZF3 | c.1296C>G p.P432= | Silent (SNP) | VAF 26/271 reads (10%) | catalogued as COSV53103329; called by muse, mutect2
- IL6ST | c.531C>T p.D177= | Silent (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- LAMC3 | c.738C>T p.D246= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as rs778312863, COSV100736068, COSV63088511; called by muse, mutect2, varscan2
- LRRK2 | c.1560C>T p.S520= | Silent (SNP) | VAF 20/347 reads (6%) | called by muse, mutect2
- MELK | c.216C>T p.L72= | Silent (SNP) | VAF 11/327 reads (3%) | called by muse, mutect2
- NHS | c.4252C>A p.R1418= | Silent (SNP) | VAF 61/180 reads (34%) | catalogued as COSV66277100, COSV66279267; called by muse, mutect2, varscan2
- OR6S1 | c.720C>T p.A240= | Silent (SNP) | VAF 76/206 reads (37%) | catalogued as rs1189482719; called by mutect2, varscan2
- PLCG2 | c.118C>A p.R40= | Silent (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- PLCG2 | c.490C>A p.R164= | Silent (SNP) | VAF 23/586 reads (4%) | catalogued as COSV63871450; called by muse, mutect2
- PSEN1 | c.453G>C p.V151= | Silent (SNP) | VAF 62/1009 reads (6%) | catalogued as rs755634855; called by muse, mutect2
- SLC2A6 | c.1488C>A p.S496= | Silent (SNP) | VAF 11/112 reads (10%) | called by muse, mutect2
- TANC1 | c.1551G>A p.L517= | Silent (SNP) | VAF 152/1422 reads (11%) | catalogued as COSV55089791; called by muse, mutect2, varscan2
- TNKS2 | c.867G>A p.R289= | Silent (SNP) | VAF 22/370 reads (6%) | catalogued as rs1467938794; called by muse, mutect2
- TRANK1 | c.6954C>G p.L2318= | Silent (SNP) | VAF 24/302 reads (8%) | catalogued as COSV100084509, COSV57143690; called by muse, mutect2
- TUT7 | c.906G>A p.V302= | Silent (SNP) | VAF 22/738 reads (3%) | called by muse, mutect2
- ZNF214 | c.495C>A p.G165= | Silent (SNP) | VAF 42/1091 reads (4%) | called by muse, mutect2
- ZNF225 | c.412C>T p.L138= | Silent (SNP) | VAF 38/650 reads (6%) | called by muse, mutect2
- DCAF13 | chr8:103415146 G>A | 5'Flank (SNP) | VAF 14/54 reads (26%) | catalogued as rs1264851443, COSV52568032; called by muse, mutect2, varscan2
